Somatic mutation profile of tumor specimen TCGA-44-7659-01A (aliquot TCGA-44-7659-01A-11D-2063-08) from TCGA case TCGA-44-7659, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.4 years (25,730 days).
Specimen TCGA-44-7659-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c414d5ad-3869-4b6d-9839-3ef77efc7d6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-7659-10A (Blood Derived Normal), aliquot TCGA-44-7659-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/844c8278-f3a1-491a-8b86-8db2523d662b

The open-access MAF lists 161 somatic variants for this specimen: 122 protein-altering or splice-affecting, 35 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 35, Frame Shift Del 7, Nonsense Mutation 6, Splice Site 2, RNA 2, 3'Flank 2, Frame Shift Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.2548G>A p.G850S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776591659, CM043272, COSV66329681, COSV66330443; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.850T>G p.Y284D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs864321706, COSV60434144; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62323135; called by muse, mutect2, varscan2
- ABI3BP | c.1357C>A p.P453T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs1241444475, COSV52536556; called by muse, mutect2, varscan2
- ABRA | c.893G>C p.R298T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61732438; called by muse, mutect2, varscan2
- AC004922.1 | c.1491G>C p.K497N | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs757287136, COSV53163352; called by muse, mutect2, varscan2
- AC005833.1 | c.1572A>C p.R524S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0); catalogued as COSV52897450, COSV52902135; called by muse, mutect2, varscan2
- ACTN1 | c.429G>C p.E143D | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV51991990; called by muse, mutect2, varscan2
- ADAMTS12 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61263264; called by muse, mutect2, varscan2
- ADGRE2 | c.952C>A p.L318M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV59693592; called by muse, mutect2, varscan2
- AKAP17A | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58309667; called by muse, mutect2, varscan2
- ALKBH2 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV54357359; called by muse, mutect2, varscan2
- ANKMY1 | c.2693A>G p.Y898C | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs776480329, COSV56034209; called by muse, mutect2, varscan2
- ATP10B | c.1741G>T p.A581S | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.192); catalogued as rs1400399776, COSV59152053; called by muse, mutect2, varscan2
- ATP13A4 | c.487C>A p.H163N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55069441; called by muse, mutect2, varscan2
- ATP6V1C2 | c.1154T>A p.F385Y (on ENST00000272238 / NM_001039362.2; = p.F339Y on NM_144583.4) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as COSV55350811; called by muse, mutect2, varscan2
- ATP8B1 | c.1204A>T p.I402F | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52175913; called by muse, mutect2, varscan2
- BCL11A | c.797T>A p.V266E (on ENST00000335712 / NM_001365609.1; = p.V300E on NM_018014.4) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV59630216; called by muse, mutect2, varscan2
- CCDC136 | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52799606; called by muse, mutect2, varscan2
- CDC27 | c.1487A>G p.Y496C | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs76995821, COSV50366319; called by muse, mutect2, varscan2
- CDIN1 | c.787A>G p.I263V (on ENST00000437989; = p.I165V on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV57711475; called by muse, mutect2, varscan2
- CHST14 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV60378767, COSV60379197; called by muse, mutect2, varscan2
- COL18A1 | c.2072C>T p.A691V (on ENST00000359759 / NM_130444.3; = p.A456V on NM_030582.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs771472612, COSV62700765; called by muse, mutect2, varscan2
- CRISP3 | c.256C>A p.P86T (on ENST00000371159 / NM_001368123.1; = p.P68T on NM_006061.4) | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53820331, COSV53821845; called by muse, mutect2, varscan2
- DNAH7 | c.9194G>T p.R3065L | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV56765344, COSV56777627; called by muse, mutect2, varscan2
- FAIM2 | c.943C>G p.R315G | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV57739161; called by muse, mutect2, varscan2
- FBN1 | c.7219A>G p.K2407E | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.334); catalogued as rs774554301, COSV57316853; called by muse, mutect2, varscan2
- FLG | c.5645G>A p.G1882E | Missense Mutation (SNP) | VAF 104/607 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs1423255883, COSV64241962; called by muse, mutect2, varscan2
- FLNC | c.3016C>A p.P1006T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57955963, COSV57957878; called by muse, mutect2, varscan2
- FRMPD1 | c.3379G>T p.E1127* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV66700473; called by muse, mutect2, varscan2
- GID4 | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV52008944; called by muse, mutect2, varscan2
- GLI3 | c.1397A>G p.D466G | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV67888649; called by muse, mutect2, varscan2
- GRB10 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.762); catalogued as COSV60010701; called by muse, mutect2, varscan2
- HKDC1 | c.2622G>T p.L874F | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.071); catalogued as COSV100664620, COSV63578485; called by muse, mutect2, varscan2
- HKDC1 | c.2623C>T p.Q875* | Nonsense Mutation (SNP) | VAF 29/120 reads (24%) | catalogued as COSV100664621; called by muse, mutect2, varscan2
- HYDIN | c.786T>A p.F262L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99863647; called by mutect2, varscan2
- IFNA8 | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66504604; called by muse, mutect2, varscan2
- IGHV1-2 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as rs529206090; called by muse, mutect2, varscan2
- IL31RA | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51681673; called by muse, mutect2, varscan2
- KBTBD7 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV65266414; called by muse, mutect2
- KCNA4 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs1473161691, COSV60252311; called by muse, mutect2, varscan2
- KIAA0100 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV66492827; called by muse, mutect2, varscan2
- KLHDC8A | c.640T>G p.F214V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV65678762; called by muse, mutect2, varscan2
- KMT2A | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV63285885; called by muse, mutect2, varscan2
- LILRA4 | c.1140C>A p.F380L | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52492316; called by muse, varscan2
- LRRC17 | c.405A>T p.L135F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50864727; called by muse, mutect2, varscan2
- MACROH2A1 | c.901G>T p.A301S (on ENST00000510038; = p.A300S on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56895421; called by muse, mutect2, varscan2
- MAPK13 | c.647T>C p.M216T | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1249024848, COSV52983138; called by muse, mutect2, varscan2
- MAX | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52416276, COSV52416985, COSV52418829; called by muse, mutect2, varscan2
- MAZ | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.857); catalogued as rs780618980, COSV99361252; called by mutect2, varscan2
- MICAL3 | c.4606G>T p.D1536Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV101490915; called by muse, mutect2, varscan2
- MICAL3 | c.4605G>T p.E1535D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV101490916; called by muse, mutect2, varscan2
- MUC5B | c.10945C>T p.Q3649* | Nonsense Mutation (SNP) | VAF 21/148 reads (14%) | catalogued as COSV71592079; called by muse, mutect2, varscan2
- MYH7 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as rs1230432463, CM034551, COSV62519303; called by muse, mutect2, varscan2
- NMUR2 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV54919373; called by muse, mutect2, varscan2
- NNT | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM158499, COSV52925143; called by muse, mutect2, varscan2
- NTRK1 | c.1462G>A p.G488S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as COSV62324393; called by muse, mutect2, varscan2
- OAS1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs778063812, COSV52535757, COSV52539446; called by muse, mutect2, varscan2
- OMG | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55988028; called by muse, mutect2, varscan2
- OR13F1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs747735410, COSV58251577; called by muse, mutect2, varscan2
- OR2L2 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs750991066, COSV63549486, COSV63550066; called by muse, mutect2, varscan2
- OR2L3 | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 138/326 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV63455219; called by muse, mutect2, varscan2
- OR2M5 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 203/462 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs1212891988, COSV63546285; called by muse, mutect2, varscan2
- OR4N2 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV60051559; called by muse, mutect2, varscan2
- OR51G2 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV58992241, COSV58992948; called by muse, mutect2
- OR8U1 | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs537232927, COSV100163763; called by muse, mutect2, varscan2
- PASD1 | c.843C>G p.A281= | Splice Region (SNP) | VAF 30/47 reads (64%) | catalogued as COSV64855333; called by muse, mutect2
- PBRM1 | c.4680+1G>T p.X1560_splice (on ENST00000296302 / NM_001366071.2; = p.X1453_splice on NM_018313.5) | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV56262009, COSV56276672; called by muse, mutect2, varscan2
- PCDHA10 | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.044); catalogued as COSV56502131; called by muse, mutect2, varscan2
- PCDHB14 | c.1422C>G p.S474R | Missense Mutation (SNP) | VAF 109/352 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.359); catalogued as rs782665639, COSV53388445; called by muse, mutect2, varscan2
- PCDHGA5 | c.2261C>A p.S754Y | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53949497, COSV54029747; called by muse, mutect2, varscan2
- POF1B | c.834T>A p.H278Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53134224; called by muse, mutect2, varscan2
- PPARA | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.089); catalogued as COSV53078625; called by muse, mutect2, varscan2
- PPP1R15A | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV52339069; called by muse, mutect2, varscan2
- PRSS35 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100864112; called by muse, mutect2, varscan2
- PRUNE2 | c.2024A>G p.E675G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs769617730, COSV65041594; called by muse, mutect2, varscan2
- PSMD6 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV55759866; called by muse, varscan2
- PTPRN | c.1370C>G p.T457R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV55348005; called by muse, mutect2, varscan2
- PUDP | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66904033; called by muse, mutect2, varscan2
- RAB3IP | c.628G>A p.E210K (on ENST00000550536 / NM_175623.4; = p.E194K on NM_022456.5) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56083557; called by muse, mutect2, varscan2
- RBM10 | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV61308625, COSV61310341; called by muse, mutect2, varscan2
- RLIM | c.703A>G p.M235V | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs754843848, COSV60326471; called by muse, mutect2, varscan2
- SBK1 | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59397014; called by muse, mutect2, varscan2
- SLC35F3 | c.1027G>T p.A343S (on ENST00000366617 / NM_001300845.1; = p.A412S on NM_173508.4) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV64019686; called by muse, mutect2, varscan2
- SMG1 | c.10429A>G p.M3477V | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs760202459, COSV67169984; called by muse, mutect2, varscan2
- SMG7 | c.2715G>T p.Q905H | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as COSV61631462; called by muse, mutect2, varscan2
- SPANXN2 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 127/325 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV65127674, COSV65128871; called by muse, varscan2
- SPTA1 | c.3508A>T p.R1170W | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV63753234; called by muse, mutect2, varscan2
- SPTA1 | c.3177G>T p.Q1059H | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV63753238; called by muse, mutect2, varscan2
- SRARP | c.30G>T p.W10C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61497793, COSV61498096; called by muse, mutect2, varscan2
- SRPX | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV59437252, COSV59438760; called by muse, mutect2, varscan2
- STAB1 | c.2601C>A p.H867Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58736287; called by muse, mutect2, varscan2
- STAB2 | c.2871C>A p.C957* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as COSV66339081; called by muse, mutect2, varscan2
- SYNPR | c.5G>T p.C2F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV55725673; called by muse, mutect2, varscan2
- TACC2 | c.8334A>T p.E2778D (on ENST00000334433; = p.E856D on NM_006997.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53281556; called by muse, mutect2, varscan2
- TEP1 | c.4451G>T p.R1484L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV52992656; called by muse, mutect2, varscan2
- TET1 | c.1957A>G p.K653E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65384807; called by muse, mutect2, varscan2
- TGM7 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036052965, COSV71772815; called by muse, mutect2, varscan2
- THNSL2 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59082969; called by muse, mutect2, varscan2
- TKFC | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs753858899, COSV67523215; called by muse, mutect2, varscan2
- TOPORS | c.3089G>T p.R1030L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV62116948, COSV99060429; called by muse, mutect2, varscan2
- TTN | c.32408G>T p.R10803M (on ENST00000591111; = p.R9876M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/210 reads (22%) | PolyPhen benign (0.444); catalogued as COSV60067898; called by muse, mutect2, varscan2
- UCK2 | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV63315377; called by muse, mutect2
- UGT2B4 | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV59317269; called by muse, mutect2, varscan2
- USP47 | c.2899A>T p.S967C (on ENST00000399455 / NM_001372095.1; = p.S879C on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV60463850; called by muse, mutect2, varscan2
- VWA3A | c.3284C>A p.A1095E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV55389775, COSV55390999; called by muse, mutect2, varscan2
- XIRP2 | c.1589G>T p.G530V (on ENST00000628543; = p.G705V on NM_152381.6) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54701009; called by muse, mutect2, varscan2
- XIRP2 | c.9255G>T p.E3085D (on ENST00000628543; = p.E3260D on NM_152381.6) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV54695003, COSV99744299; called by muse, mutect2, varscan2
- XIRP2 | c.9256G>T p.E3086* (on ENST00000628543; = p.E3261* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV54689382, COSV99744303; called by muse, mutect2, varscan2
- ZNF211 | c.693G>T p.W231C (on ENST00000347302 / NM_198855.4; = p.W244C on NM_006385.5) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV53742017; called by muse, mutect2, varscan2
- ZNF431 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV60673089; called by muse, mutect2, varscan2
- ZNF492 | c.1433A>T p.K478M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71761969; called by muse, mutect2, varscan2
- ZP1 | c.1775-1G>C p.X592_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53924372; called by muse, mutect2, varscan2
- ALOX12 | c.1651_1659del p.Y551_W553del | In Frame Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- COL21A1 | c.300del p.T101Rfs*10 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- DHX38 | c.2088dup p.G697Wfs*16 | Frame Shift Ins (INS) | VAF 28/108 reads (26%) | called by mutect2, pindel, varscan2
- DRD3 | c.985del p.Q329Kfs*19 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by pindel, varscan2
- DRD3 | c.943del p.L315Cfs*33 | Frame Shift Del (DEL) | VAF 26/136 reads (19%) | called by pindel, varscan2
- GLS2 | c.949del p.T317Qfs*24 | Frame Shift Del (DEL) | VAF 54/245 reads (22%) | called by mutect2, pindel, varscan2
- SERPINB11 | c.1132_1133del p.T378Sfs*20 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | called by pindel, varscan2
- SFRP4 | c.129del p.N44Tfs*24 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- TTN | c.87364del p.S29122Afs*5 (on ENST00000591111; = p.S21698Afs*5 on NM_003319.4) | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- AC100868.1 | c.1296G>C p.L432= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV51842990; called by muse, mutect2, varscan2
- ASTN2 | c.663G>T p.L221= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV57778562; called by muse, mutect2, varscan2
- BTNL2 | c.6G>A p.V2= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV66630743; called by muse, mutect2, varscan2
- COL4A4 | c.3777A>T p.P1259= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV61632254; called by muse, mutect2
- CUBN | c.852A>G p.Q284= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV64715986; called by muse, mutect2, varscan2
- EEF2 | c.834C>A p.T278= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as rs966682807, COSV58579531; called by muse, mutect2, varscan2
- EVX2 | c.531G>A p.A177= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs923392475, COSV57963375; called by mutect2, varscan2
- EVX2 | c.261C>A p.T87= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100420889, COSV57963383; called by muse, mutect2, varscan2
- FAM171A1 | c.783T>A p.L261= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV65316163; called by muse, mutect2, varscan2
- FAT2 | c.1284C>T p.H428= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as rs1180287919, COSV55819874; called by muse, mutect2, varscan2
- HNRNPD | c.540G>T p.P180= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV58313712; called by muse, mutect2, varscan2
- IGKV6D-41 | c.13T>C p.L5= | Silent (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- KLF12 | c.684C>T p.P228= | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as COSV66573671; called by muse, mutect2, varscan2
- KMT2C | c.8127C>T p.V2709= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs531059054, COSV51440370; called by muse, mutect2, varscan2
- LLGL1 | c.210C>T p.G70= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV57498047; called by mutect2, varscan2
- MORC3 | c.1965T>A p.V655= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV68688352; called by muse, mutect2, varscan2
- OR10AG1 | c.144T>C p.T48= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV56632942; called by muse, mutect2
- OR11L1 | c.843C>A p.V281= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV63314561; called by muse, mutect2, varscan2
- OR51S1 | c.840T>C p.H280= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as rs778501355, COSV59058458; called by muse, mutect2, varscan2
- OR5R1 | c.375C>A p.A125= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV56572355; called by muse, mutect2, varscan2
- PCDH11X | c.3591C>T p.H1197= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs1309391729, COSV53466772; called by muse, mutect2
- PCSK7 | c.1560A>G p.S520= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV54063327; called by muse, mutect2, varscan2
- PDGFRB | c.108A>T p.T36= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV55804678; called by muse, mutect2, varscan2
- PLCG2 | c.1329G>T p.S443= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV63869571; called by muse, mutect2, varscan2
- PNLIPRP3 | c.336G>A p.Q112= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV65048155, COSV65049566; called by muse, mutect2, varscan2
- PTH2 | c.193C>T p.L65= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV54528367; called by muse, mutect2
- PTPRD | c.3189G>T p.V1063= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV61946776; called by muse, mutect2, varscan2
- SEMA3D | c.1938G>T p.T646= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV52393598, COSV52400481; called by muse, mutect2, varscan2
- SIGLEC9 | c.399C>T p.H133= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs748102098, COSV51584493; called by muse, mutect2, varscan2
- SLC17A8 | c.1230G>A p.S410= | Silent (SNP) | VAF 39/173 reads (23%) | catalogued as rs1489915828, COSV60122846; called by muse, mutect2, varscan2
- SLC45A2 | c.1101C>A p.V367= | Silent (SNP) | VAF 65/184 reads (35%) | catalogued as COSV56869515, COSV56871929; called by muse, mutect2, varscan2
- SPPL2C | c.246C>A p.R82= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV61292497; called by muse, mutect2, varscan2
- TDRKH | c.57G>T p.L19= | Silent (SNP) | VAF 42/187 reads (22%) | catalogued as COSV64316334; called by muse, mutect2, varscan2
- TEX35 | c.168C>G p.L56= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV51105074; called by muse, mutect2, varscan2
- VAV1 | c.112C>A p.R38= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV100409605, COSV58383731; called by muse, mutect2, varscan2
- DNM1P46 | n.858G>T | RNA (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- LRP6 | chr12:12112002 C>A | 3'Flank (SNP) | VAF 30/153 reads (20%) | called by muse, mutect2, varscan2
- TRPV2 | chr17:16439176 C>T | 3'Flank (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- UBTFL2 | n.560C>A | RNA (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
